CCDI case PBCNVK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/56e890bb-de12-4dee-ac5d-32f1e2d66ad2

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Plexiform fibrohistiocytic tumor: ICD-O-3 morphology code: 8835/1; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 15.8 years (5,780 days).

Biospecimens (3 samples)
- Sample 0DWERR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWWMB: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DWWN2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
